Gene-level copy-number profile of tumor specimen TCGA-AH-6544-01A from TCGA case TCGA-AH-6544, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 60.2 years (21,977 days).
Specimen TCGA-AH-6544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.56656adc-b339-46f2-b981-f3abf898fcf8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AH-6544-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ee6690a5-f979-44c0-83da-4b8775f25bd6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 823; copy number 2: 23,170; copy number 3: 24,135; copy number 4: 8,476; copy number 5: 3,201; copy number 6: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AH-6544-01A-11D-1825-01): tumor purity 0.46, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,748,969, 4 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr18:68,673,688–69,055,189, 9 genes: TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
